Somatic mutation profile of cancer-model specimen HCM-BROD-0448-C15-85M (3D Organoid, passage 4; aliquot HCM-BROD-0448-C15-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0448-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Age at diagnosis: 78.6 years (28,714 days).
Specimen HCM-BROD-0448-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1655196-cf36-4d06-ac59-2f0daf0fe02b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0448-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0448-C15-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d53cba5f-8049-40e8-8601-7c8ee561c6e4

The open-access MAF lists 137 somatic variants for this specimen: 108 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 25, Nonsense Mutation 4, Frame Shift Ins 3, In Frame Del 2, Intron 2, 5'UTR 1, Splice Region 1, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 218/341 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ASB4 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV99987218, COSV99987246; called by muse, mutect2, varscan2
- AXL | c.2399G>A p.R800Q (on ENST00000301178 / NM_021913.5; = p.R791Q on NM_001699.6) | Missense Mutation (SNP) | VAF 90/437 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199709000; called by muse, mutect2, varscan2
- CA6 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 207/359 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs184168475; called by muse, mutect2, varscan2
- CACNA2D1 | c.2018C>T p.S673L (on ENST00000356253 / NM_001366867.1; = p.S661L on NM_000722.4) | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs779137994, COSV62373938; called by muse, mutect2, varscan2
- CCDC173 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754874295; called by muse, mutect2, varscan2
- CD1C | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 194/416 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV100939479; called by muse, mutect2, varscan2
- CDKN2A | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 404/407 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as CD994409, COSV58703816; called by muse, mutect2, varscan2
- CDKN2A | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 368/369 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs878853646, CD111993, CD961883, CM960271, COSV58683653, COSV58684450, COSV58705440; ClinVar: uncertain significance; called by muse, varscan2
- CHD7 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 335/615 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.182); catalogued as COSV101418023; called by muse, mutect2, varscan2
- COQ8A | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 198/460 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV62010629; called by muse, mutect2, varscan2
- CP | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs758399451, COSV52831503; called by muse, mutect2, varscan2
- CPZ | c.833G>A p.R278H (on ENST00000360986 / NM_001014447.3; = p.R267H on NM_003652.3) | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs773276230; called by muse, mutect2, varscan2
- CTNNA2 | c.2575-1G>T p.X859_splice (on ENST00000402739 / NM_001282597.3; = p.X811_splice on NM_004389.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 103/104 reads (99%) | catalogued as COSV58131567; called by muse, mutect2, varscan2
- CTNND1 | c.1960C>T p.R654* (on ENST00000399050 / NM_001085458.2; = p.R648* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 158/158 reads (100%) | catalogued as COSV100650349; called by muse, mutect2, varscan2
- DOK4 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1277329947, COSV54673701; called by muse, varscan2
- EN1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 610/612 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs1180306542; called by muse, mutect2, varscan2
- GALNTL6 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759011560, COSV101560117, COSV72490120; called by muse, mutect2, varscan2
- GRM5 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100555154; called by muse, mutect2, varscan2
- GTF2H4 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 371/639 reads (58%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV104389948; called by muse, mutect2, varscan2
- GZMK | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs202051718, COSV50244331; called by muse, mutect2, varscan2
- KCNQ3 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 140/376 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV66463149; called by muse, mutect2, varscan2
- LRRK1 | c.5743G>A p.V1915I | Missense Mutation (SNP) | VAF 366/487 reads (75%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs775588013, COSV52628754; called by muse, mutect2, varscan2
- MYF5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 221/321 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1289442350, COSV57356011; called by muse, mutect2, varscan2
- MYO15B | c.8373dup p.R2792Afs*9 | Frame Shift Ins (INS) | VAF 104/356 reads (29%) | catalogued as rs1568233665; called by mutect2, pindel, varscan2
- NPAS3 | c.1703G>A p.R568Q (on ENST00000356141 / NM_001164749.2; = p.R536Q on NM_022123.3) | Missense Mutation (SNP) | VAF 140/440 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1049952145, COSV60833847; called by muse, varscan2
- NRDC | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 178/274 reads (65%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs768764407, COSV61405177; called by muse, mutect2, varscan2
- OR10Q1 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 138/428 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as rs142760898; called by muse, varscan2
- OR4C12 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.287); catalogued as COSV58860061, COSV58860670; called by muse, mutect2, varscan2
- PAX8 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 93/380 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54510827; called by muse, mutect2, varscan2
- PCDHB6 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 190/282 reads (67%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.068); catalogued as rs782110772, COSV50714923, COSV50738202; called by muse, varscan2
- PER2 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 340/340 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs745547801, COSV99612764; called by muse, varscan2
- PHKG2 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs532137455, COSV60312800; called by muse, mutect2, varscan2
- POSTN | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as rs370902652; called by muse, mutect2, varscan2
- PPP1CA | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 385/385 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as rs1273880415, COSV56702423; called by muse, mutect2, varscan2
- RBFOX3 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 170/276 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1477183313; called by muse, mutect2, varscan2
- RHOBTB3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 90/151 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs763502813, COSV101183270; called by muse, mutect2, varscan2
- RSF1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 266/269 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as rs751215835, COSV57837366; called by mutect2, varscan2
- SLC66A2 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs760461464; called by muse, mutect2, varscan2
- SLC6A9 | c.1928G>A p.R643H (on ENST00000360584 / NM_201649.4; = p.R589H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs141553063; called by muse, mutect2, varscan2
- STAP2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs145893074; called by muse, mutect2, varscan2
- TENM2 | c.4237C>T p.R1413C (on ENST00000518659 / NM_001122679.2; = p.R1174C on NM_001080428.3) | Missense Mutation (SNP) | VAF 132/208 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV69136530; called by muse, mutect2, varscan2
- TMEM151B | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 176/580 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1363984774; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 116/326 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, varscan2
- TREM1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs1018046222, COSV55148255; called by muse, mutect2, varscan2
- WDR45B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 129/217 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753663465, COSV101124421, COSV66408248; called by muse, mutect2, varscan2
- ZC3H3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 399/856 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs776395632, COSV52794799; called by muse, mutect2, varscan2
- ZHX2 | c.2395G>A p.G799R | Missense Mutation (SNP) | VAF 301/581 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs752370410, COSV100073974, COSV58712967; called by muse, mutect2, varscan2
- ZP3 | c.476C>A p.P159H (on ENST00000394857 / NM_001110354.2; = p.P108H on NM_007155.6) | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60633713; called by muse, mutect2, varscan2
- ACAD9 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AIM2 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 203/420 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- AP1G2 | c.844A>G p.S282G | Missense Mutation (SNP) | VAF 151/256 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARID1B | c.3277_3283del p.C1093Kfs*22 | Frame Shift Del (DEL) | VAF 146/361 reads (40%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AUTS2 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 207/725 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRSK2 | c.1810_1812del p.E604del | In Frame Del (DEL) | VAF 119/395 reads (30%) | called by mutect2, pindel, varscan2
- C2orf91 | n.475G>C | Splice Region (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- CFH | c.3026A>C p.K1009T | Missense Mutation (SNP) | VAF 179/353 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CHSY3 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 332/547 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CNPPD1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 245/491 reads (50%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DDX1 | c.568_570del p.D190del | In Frame Del (DEL) | VAF 42/218 reads (19%) | called by mutect2, pindel, varscan2
- DDX43 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 109/267 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ECM2 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTPD1 | c.1099A>G p.M367V | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FAM71A | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 172/289 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FLACC1 | c.1254T>A p.C418* | Nonsense Mutation (SNP) | VAF 209/211 reads (99%) | called by muse, mutect2, varscan2
- FSIP2 | c.12028T>C p.F4010L | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- GABRG3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 105/171 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GDF6 | c.938G>A p.W313* | Nonsense Mutation (SNP) | VAF 76/383 reads (20%) | called by muse, mutect2, varscan2
- GNMT | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 354/551 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRHL2 | c.1246T>C p.F416L | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK2 | c.2352G>T p.Q784H | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- HCN1 | c.1845C>A p.N615K | Missense Mutation (SNP) | VAF 202/333 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HDLBP | c.2300A>C p.E767A | Missense Mutation (SNP) | VAF 185/424 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HMCN1 | c.12232C>T p.P4078S | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IBTK | c.2289dup p.C764Mfs*6 | Frame Shift Ins (INS) | VAF 125/285 reads (44%) | called by mutect2, pindel, varscan2
- IGDCC3 | c.1349A>C p.N450T | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- KCNH4 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KCNH4 | c.601A>C p.K201Q | Missense Mutation (SNP) | VAF 122/209 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KIF2B | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- LURAP1L | c.135_147delinsAGCGGTGGTGGTGGCGGCGGC p.S46Afs*51 | Frame Shift Ins (INS) | VAF 6/70 reads (9%) | called by mutect2*, pindel
- MAP4K1 | c.2177A>T p.D726V | Missense Mutation (SNP) | VAF 420/420 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MAPK4 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL24 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.103); called by mutect2, varscan2
- MFSD11 | c.938T>C p.L313S | Missense Mutation (SNP) | VAF 217/343 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MMS22L | c.3241A>T p.K1081* | Nonsense Mutation (SNP) | VAF 174/278 reads (63%) | called by muse, mutect2, varscan2
- MYCBP2 | c.13414G>A p.E4472K (on ENST00000357337; = p.E4510K on NM_015057.5) | Missense Mutation (SNP) | VAF 135/225 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PPP2R3C | c.803A>C p.N268T | Missense Mutation (SNP) | VAF 125/201 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SH3BP5 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 341/342 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SIRPG | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 90/407 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SMCO2 | c.917C>A p.T306K | Missense Mutation (SNP) | VAF 214/348 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SOX17 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 565/1014 reads (56%) | SIFT tolerated (0.94); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPSB3 | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPTBN5 | c.2258A>G p.D753G | Missense Mutation (SNP) | VAF 122/434 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SSC5D | c.4256A>T p.N1419I | Missense Mutation (SNP) | VAF 146/645 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLCD2 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 306/458 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- TMEM132E | c.2647G>A p.G883S (on ENST00000321639; = p.G973S on NM_001304438.2) | Missense Mutation (SNP) | VAF 144/548 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- TPSD1 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRAV23DV6 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 206/312 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIL | c.2254G>T p.G752C | Missense Mutation (SNP) | VAF 228/727 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRIO | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 129/356 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TSPYL5 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 478/860 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ULK4 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- USH1G | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 145/539 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VANGL2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 142/236 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- VARS2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 312/553 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF846 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 132/133 reads (99%) | SIFT tolerated (0.17); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- ZXDB | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 411/781 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASRGL1 | c.420G>T p.V140= | Silent (SNP) | VAF 337/337 reads (100%) | called by muse, mutect2, varscan2
- BMP3 | c.366C>T p.T122= | Silent (SNP) | VAF 79/185 reads (43%) | called by muse, mutect2, varscan2
- CFHR1 | c.897G>T p.V299= | Silent (SNP) | VAF 203/348 reads (58%) | called by muse, mutect2, varscan2
- CHD8 | c.204T>G p.P68= | Silent (SNP) | VAF 100/310 reads (32%) | called by muse, mutect2, varscan2
- DIDO1 | c.633C>T p.G211= | Silent (SNP) | VAF 118/977 reads (12%) | catalogued as rs1240560188, COSV56621860; called by muse, mutect2, varscan2
- EXT1 | c.1104C>T p.F368= | Silent (SNP) | VAF 95/570 reads (17%) | called by muse, mutect2, varscan2
- IL12RB1 | c.708C>T p.P236= | Silent (SNP) | VAF 221/221 reads (100%) | called by muse, mutect2, varscan2
- ITSN1 | c.894C>T p.V298= | Silent (SNP) | VAF 74/250 reads (30%) | called by muse, mutect2, varscan2
- KIAA1109 | c.1917C>T p.N639= | Silent (SNP) | VAF 80/80 reads (100%) | catalogued as rs373929838; called by muse, mutect2, varscan2
- LRRC41 | c.795C>T p.L265= | Silent (SNP) | VAF 249/361 reads (69%) | catalogued as rs1366456257; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.216C>T p.S72= | Silent (SNP) | VAF 182/499 reads (36%) | catalogued as rs1263992797; called by muse, mutect2, varscan2
- MYH3 | c.4932C>T p.L1644= | Silent (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- NCAM1 | c.1746C>T p.Y582= (on ENST00000316851 / NM_181351.5; = p.Y572= on NM_000615.7) | Silent (SNP) | VAF 377/377 reads (100%) | catalogued as rs3741072; called by muse, mutect2, varscan2
- NR4A3 | c.576C>T p.H192= | Silent (SNP) | VAF 356/356 reads (100%) | catalogued as rs761297484; called by muse, mutect2, varscan2
- NRXN1 | c.2658C>T p.G886= | Silent (SNP) | VAF 277/277 reads (100%) | catalogued as rs752920557, COSV58468328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPLN | c.483C>T p.H161= | Silent (SNP) | VAF 108/304 reads (36%) | catalogued as rs774419908; called by muse, mutect2, varscan2
- PLEKHG6 | c.615T>G p.A205= | Silent (SNP) | VAF 80/240 reads (33%) | called by muse, varscan2
- SCN8A | c.2775C>T p.S925= | Silent (SNP) | VAF 142/448 reads (32%) | called by muse, mutect2, varscan2
- SCN9A | c.1545C>T p.H515= | Silent (SNP) | VAF 143/375 reads (38%) | called by muse, mutect2, varscan2
- SLC47A1 | c.1677G>T p.V559= | Silent (SNP) | VAF 72/223 reads (32%) | called by muse, mutect2, varscan2
- TAS2R30 | c.306C>T p.L102= | Silent (SNP) | VAF 107/379 reads (28%) | called by muse, mutect2, varscan2
- THOC2 | c.2613A>G p.K871= | Silent (SNP) | VAF 290/290 reads (100%) | called by muse, mutect2, varscan2
- TNK2 | c.2733G>A p.P911= | Silent (SNP) | VAF 258/403 reads (64%) | catalogued as rs373899133; called by muse, mutect2, varscan2
- TTLL2 | c.339G>A p.K113= | Silent (SNP) | VAF 138/630 reads (22%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.333A>G p.A111= | Silent (SNP) | VAF 264/404 reads (65%) | called by muse, varscan2
- PDPN | c.-158G>A | 5'UTR (SNP) | VAF 308/491 reads (63%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2524G>A | Intron (SNP) | VAF 101/293 reads (34%) | catalogued as rs909060982; called by muse, mutect2, varscan2
- RIMBP2 | c.102+8208C>T | Intron (SNP) | VAF 87/196 reads (44%) | catalogued as rs762528299; called by muse, varscan2
- SEPTIN3 | chr22:41972084 C>T | 5'Flank (SNP) | VAF 178/280 reads (64%) | catalogued as rs1448813820; called by muse, mutect2, varscan2
